Somatic mutation profile of tumor specimen TCGA-CQ-5323-01A (aliquot TCGA-CQ-5323-01A-01D-1683-08) from TCGA case TCGA-CQ-5323, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 82.6 years (30,173 days).
Specimen TCGA-CQ-5323-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa51e694-340f-4248-b336-0e69ac43cdae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-5323-10A (Blood Derived Normal), aliquot TCGA-CQ-5323-10A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de6097c9-1944-4f36-be33-eb635777bbce

The open-access MAF lists 62 somatic variants for this specimen: 49 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 11, Nonsense Mutation 6, Frame Shift Del 4, Frame Shift Ins 3, Splice Site 1, Splice Region 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGTPBP1 | c.3200C>T p.A1067V (on ENST00000357081 / NM_001330701.2; = p.A1027V on NM_015239.2) | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as COSV100430237; called by muse, mutect2, varscan2
- BAHD1 | c.2320C>T p.R774C | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100087087; called by muse, mutect2, varscan2
- BOLL | c.353-2A>C p.X118_splice | Splice Site (SNP) | VAF 17/114 reads (15%) | catalogued as COSV99987416; called by muse, mutect2, varscan2
- BRINP1 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs987725274, COSV56293277; called by muse, mutect2, varscan2
- CCDC191 | c.1885C>G p.P629A | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as COSV99878749; called by muse, mutect2, varscan2
- CCNA1 | c.1075G>A p.V359I | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs748235047, COSV55221766; called by muse, mutect2, varscan2
- CSMD1 | c.6293A>G p.Y2098C (on ENST00000520002; = p.Y2097C on NM_033225.6) | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.52); catalogued as COSV100153561; called by muse, mutect2, varscan2
- DNAH9 | c.8962G>C p.A2988P | Missense Mutation (SNP) | VAF 11/222 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV99308060; called by muse, mutect2
- DPP10 | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.484); catalogued as rs537818684, COSV100071625; called by muse, mutect2, varscan2
- EGFLAM | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.845); catalogued as rs369204325, COSV59305298; called by muse, mutect2, varscan2
- EMC2 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 6/80 reads (8%) | catalogued as COSV99624555; called by muse, mutect2
- FIG4 | c.1910C>T p.P637L | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1213301775, COSV100020245; called by muse, mutect2
- GCKR | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99269435; called by muse, mutect2, varscan2
- GRIK3 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs141595955; called by muse, mutect2, varscan2
- ITGA1 | c.3151A>G p.T1051A | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs1384831707, COSV99252136; called by muse, mutect2, varscan2
- KCNMB2 | c.225G>A p.Q75= | Splice Region (SNP) | VAF 50/325 reads (15%) | catalogued as COSV100844033; called by muse, mutect2, varscan2
- KMT2D | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 27/124 reads (22%) | catalogued as COSV99985672; called by muse, mutect2, varscan2
- LAMC3 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377375857; called by muse, mutect2
- LINGO2 | c.1228C>A p.P410T | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs199551773, COSV58056464; called by muse, mutect2, varscan2
- MRTFA | c.982G>T p.E328* | Nonsense Mutation (SNP) | VAF 7/93 reads (8%) | catalogued as COSV100844365, COSV62932556; called by muse, mutect2
- NELL1 | c.2326C>G p.L776V | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.371); catalogued as COSV100125035; called by muse, mutect2
- NKTR | c.89A>G p.D30G | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99236338; called by muse, mutect2, varscan2
- PAX5 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100814600; called by muse, mutect2
- PCDHB15 | c.1532G>T p.G511V | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV51427916, COSV99179205; called by muse, mutect2, varscan2
- PDE11A | c.1616T>C p.F539S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99614880; called by muse, mutect2, varscan2
- PDZRN3 | c.2971C>T p.R991W | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55208660; called by muse, mutect2, varscan2
- PLEKHA1 | c.862A>G p.I288V | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.178); catalogued as COSV100935590; called by muse, mutect2, varscan2
- PZP | c.931G>C p.G311R | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV99739413; called by muse, mutect2, varscan2
- SBF1 | c.1155C>A p.C385* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as rs1470054201, COSV100818028; called by muse, mutect2, varscan2
- SCAF4 | c.1801del p.Y601Ifs*75 | Frame Shift Del (DEL) | VAF 22/87 reads (25%) | catalogued as COSV54590825; called by mutect2, pindel, varscan2
- SSUH2 | c.502G>C p.G168R | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); catalogued as COSV100435607, COSV58029454; called by muse, mutect2, varscan2
- TAF5 | c.1888G>T p.V630L | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV100428305; called by muse, mutect2, varscan2
- TAS2R16 | c.845C>T p.T282M | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs755510148, COSV50797989, COSV50798071; called by muse, mutect2, varscan2
- TET1 | c.3144C>A p.C1048* | Nonsense Mutation (SNP) | VAF 20/102 reads (20%) | catalogued as COSV101018872; called by muse, mutect2, varscan2
- UNC5A | c.521A>G p.E174G | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99995055; called by muse, mutect2
- VWA7 | c.2173G>A p.V725I | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.608); catalogued as COSV100991985; called by muse, mutect2, varscan2
- ZFAND6 | c.52T>G p.C18G | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99928921; called by muse, mutect2, varscan2
- ZNF236 | c.1723T>A p.F575I | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99468536; called by muse, mutect2
- ZNF394 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.578); catalogued as COSV100460049, COSV100460371; called by muse, mutect2, varscan2
- ZNF479 | c.1543C>T p.H515Y | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV58639077; called by muse, mutect2
- ZNF484 | c.1526C>A p.S509* | Nonsense Mutation (SNP) | VAF 44/182 reads (24%) | catalogued as COSV100214694, COSV100214869; called by muse, mutect2, varscan2
- ZNF761 | c.1790A>G p.Q597R | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100483474; called by muse, mutect2, varscan2
- ASAH2 | c.1837C>T p.L613F | Missense Mutation (SNP) | VAF 62/186 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD163 | c.2982dup p.E995* | Frame Shift Ins (INS) | VAF 22/74 reads (30%) | called by mutect2, pindel, varscan2
- GPR17 | c.1050dup p.S351Qfs*31 | Frame Shift Ins (INS) | VAF 28/96 reads (29%) | called by mutect2, pindel, varscan2
- KRT5 | c.824dup p.K276Efs*19 | Frame Shift Ins (INS) | VAF 76/244 reads (31%) | called by mutect2, pindel, varscan2
- LRBA | c.7127del p.N2376Ifs*6 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | called by mutect2, pindel, varscan2
- PARD3 | c.1059_1068del p.I353Mfs*39 | Frame Shift Del (DEL) | VAF 38/120 reads (32%) | called by mutect2, pindel, varscan2
- TBC1D10A | c.1393_1406del p.P465Afs*35 | Frame Shift Del (DEL) | VAF 20/200 reads (10%) | called by mutect2, pindel
- DPYSL4 | c.321C>T p.H107= | Silent (SNP) | VAF 31/118 reads (26%) | catalogued as rs371272756; called by muse, mutect2, varscan2
- FNBP1 | c.234C>T p.N78= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs758858855, COSV63088278; called by muse, mutect2, varscan2
- GABBR2 | c.240C>T p.A80= | Silent (SNP) | VAF 13/21 reads (62%) | catalogued as COSV52317132; called by muse, mutect2, varscan2
- LYZL1 | c.426C>T p.V142= (on ENST00000375500; = p.V96= on NM_032517.6) | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as rs192018509, COSV64966094; called by muse, mutect2, varscan2
- PKHD1L1 | c.3390C>T p.P1130= | Silent (SNP) | VAF 59/150 reads (39%) | catalogued as rs1263560106, COSV65744370; called by muse, mutect2, varscan2
- PTCHD3 | c.2250C>T p.F750= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV101438967; called by muse, mutect2, varscan2
- RD3 | c.492C>T p.S164= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV100879237; called by muse, mutect2, varscan2
- SLC13A5 | c.919C>A p.R307= | Silent (SNP) | VAF 30/208 reads (14%) | catalogued as COSV99546175; called by muse, mutect2, varscan2
- SLC25A17 | c.489G>A p.S163= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs1319748016, COSV99610648, COSV99610784; called by muse, mutect2, varscan2
- TOLLIP | c.507C>T p.V169= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs1274975834, COSV99719719; called by muse, mutect2, varscan2
- TRIOBP | c.1353C>T p.P451= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as rs55853304, COSV100731113; called by muse, varscan2
- IGHV1-12 | n.31G>T | RNA (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- MGAM | c.4618+1151G>A | Intron (SNP) | VAF 17/106 reads (16%) | catalogued as COSV101527743; called by muse, mutect2, varscan2
